Somatic mutation profile of tumor specimen TCGA-A3-3349-01A (aliquot TCGA-A3-3349-01A-01D-1251-10) from TCGA case TCGA-A3-3349, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 34.0 years (12,431 days).
Specimen TCGA-A3-3349-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e27423ae-6443-4a58-8c10-0570f15f878f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3349-11A (Solid Tissue Normal), aliquot TCGA-A3-3349-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ce8d63e-86b2-4087-8463-2e9801fe514f

The open-access MAF lists 37 somatic variants for this specimen: 32 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 25, Silent 5, Frame Shift Del 5, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD10 | c.2974G>A p.D992N | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV58155094; called by muse, mutect2, varscan2
- ACSL5 | c.329A>T p.Q110L (on ENST00000354273; = p.Q166L on NM_016234.3) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV61129586; called by muse, mutect2, varscan2
- ADAMTS12 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV61258410; called by muse, mutect2, varscan2
- AFTPH | c.2506del p.D836Tfs*20 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as COSV99480829; called by mutect2, pindel, varscan2
- AGL | c.3682C>G p.R1228G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as CM960018, COSV54049415, COSV99649605; called by muse, mutect2, varscan2
- ARPC2 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV55283989; called by muse, mutect2, varscan2
- ATP5F1A | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56359827; called by muse, mutect2, varscan2
- BCAS3 | c.2204A>G p.H735R (on ENST00000390652 / NM_001353144.2; = p.H720R on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766203199, COSV66771299; called by muse, varscan2
- CHRNA2 | c.842G>C p.C281S | Missense Mutation (SNP) | VAF 97/403 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as COSV53556906; called by muse, mutect2, varscan2
- COL6A3 | c.3734G>A p.G1245E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV55083814; called by muse, varscan2
- CYP4B1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs752316206, COSV54721991; called by muse, mutect2, varscan2
- DDAH1 | c.414T>G p.F138L | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV52302053; called by muse, mutect2, varscan2
- EPS8L1 | c.1504C>T p.R502W (on ENST00000201647 / NM_133180.3; = p.R375W on NM_017729.3) | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1383036223, COSV52380715; called by muse, mutect2, varscan2
- GPR15 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99423933; called by muse, mutect2, varscan2
- IQCG | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 133/558 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54561071; called by muse, mutect2, varscan2
- LRRC8E | c.1088T>C p.F363S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1206230238, COSV60717334; called by muse, mutect2, varscan2
- MSX2 | c.595A>T p.R199* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV53326707; called by muse, mutect2, varscan2
- NRXN1 | c.2972T>G p.V991G | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58442445; called by muse, mutect2, varscan2
- RGL4 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.781); catalogued as COSV51943425; called by muse, mutect2, varscan2
- RGS3 | c.959G>C p.R320P (on ENST00000350696 / NM_001282923.2; = p.R208P on NM_017790.4) | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58278386; called by muse, mutect2, varscan2
- RPS6KA6 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53117734; called by muse, mutect2
- SIRPG | c.928T>A p.W310R | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV53806534; called by muse, mutect2, varscan2
- THADA | c.1266C>G p.H422Q | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777760369, COSV57679179; called by muse, mutect2, varscan2
- TMC5 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs774529822, COSV66866310; called by muse, mutect2, varscan2
- TRIM21 | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54343202; called by muse, mutect2, varscan2
- VHL | c.533del p.L178Rfs*24 | Frame Shift Del (DEL) | VAF 25/95 reads (26%) | catalogued as CM003061, CM941386, CM961439, COSV56544319, COSV56547906, COSV56565675; called by mutect2, pindel, varscan2
- ZFHX3 | c.6791A>C p.N2264T | Missense Mutation (SNP) | VAF 73/333 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as COSV51712714; called by muse, mutect2, varscan2
- CCSER1 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- CDKN3 | c.212_229del p.G71_F76del | In Frame Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- PODXL2 | c.1592del p.K531Sfs*41 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- SCPEP1 | c.641del p.P214Lfs*25 | Frame Shift Del (DEL) | VAF 43/230 reads (19%) | called by mutect2, pindel, varscan2
- TEC | c.1143del p.F381Lfs*4 | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | called by mutect2, pindel, varscan2
- CCDC170 | c.780G>A p.L260= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1391220491, COSV53338217; called by muse, mutect2
- DCAF6 | c.2292A>T p.V764= (on ENST00000312263 / NM_001349778.1; = p.V784= on NM_018442.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV56576485; called by muse, mutect2, varscan2
- PMS2 | c.429T>C p.I143= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs35650314, COSV56219832; called by muse, mutect2, varscan2
- SYT12 | c.483G>A p.E161= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV67353596; called by muse, mutect2, varscan2
- USP36 | c.3168T>G p.A1056= | Silent (SNP) | VAF 65/285 reads (23%) | catalogued as COSV61750862; called by muse, mutect2, varscan2
